Somatic mutation profile of tumor specimen TCGA-66-2778-01A (aliquot TCGA-66-2778-01A-02D-1522-08) from TCGA case TCGA-66-2778, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.7 years (25,080 days).
Specimen TCGA-66-2778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8af4c3ed-744e-445c-be58-1cbf168df99d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2778-11A (Solid Tissue Normal), aliquot TCGA-66-2778-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1aea8b04-07ea-4e78-ac04-9cafa598f942

The open-access MAF lists 145 somatic variants for this specimen: 98 protein-altering or splice-affecting, 41 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 41, Nonsense Mutation 6, Intron 4, RNA 2, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.13223A>T p.Y4408F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV101291228; called by muse, mutect2, varscan2
- ADCY2 | c.1429T>C p.F477L | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57875464; called by muse, varscan2
- ADCY2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV57875477, COSV57878362; called by muse, varscan2
- ALPK2 | c.50C>T p.T17I | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64493578; called by muse, mutect2, varscan2
- ASMTL | c.576C>G p.D192E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67243854; called by muse, varscan2
- ATP6V1B1 | c.290C>A p.S97* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as COSV52268503, COSV52269771; called by muse, mutect2, varscan2
- BCO2 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV63063591; called by muse, varscan2
- BLCAP | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as COSV50351130; called by muse, mutect2, varscan2
- CASP10 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs770997816, COSV53778704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPERB | c.1817C>A p.A606E | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs1375684136, COSV56427292, COSV56429724; called by muse, mutect2, varscan2
- CDH12 | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as COSV66409673; called by muse, mutect2, varscan2
- CFAP43 | c.3800G>C p.R1267T | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV63853064, COSV63853310; called by muse, mutect2
- CHD9 | c.8521G>C p.E2841Q (on ENST00000398510 / NM_001382353.1; = p.E2825Q on NM_025134.7) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.89); catalogued as rs1386744080, COSV54611186; called by muse, mutect2
- CKAP5 | c.605C>A p.P202Q | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV56368505, COSV56373382; called by muse, mutect2, varscan2
- COL9A1 | c.2446C>G p.R816G | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57878441, COSV57885090; called by muse, mutect2, varscan2
- CSMD3 | c.2194G>C p.V732L (on ENST00000297405 / NM_001363185.1; = p.V628L on NM_052900.3) | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV52196498; called by muse, mutect2, varscan2
- DCAF5 | c.1927C>T p.Q643* | Nonsense Mutation (SNP) | VAF 10/164 reads (6%) | catalogued as COSV58460729; called by muse, mutect2
- DENND2D | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV62959239; called by muse, mutect2, varscan2
- DHRS7C | c.566G>T p.R189L (on ENST00000330255 / NM_001220493.2; = p.R188L on NM_001105571.3) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57649744, COSV57651074; called by muse, mutect2, varscan2
- DHTKD1 | c.1673C>G p.S558C | Missense Mutation (SNP) | VAF 39/368 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs373710565; called by muse, mutect2
- DTNBP1 | c.246G>A p.M82I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.709); catalogued as COSV59040558; called by muse, mutect2, varscan2
- FAM47C | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV63726013; called by muse, mutect2, varscan2
- FBN3 | c.4313G>C p.R1438P | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as rs781626312, COSV54462502; called by muse, mutect2, varscan2
- FCRL2 | c.994T>C p.Y332H | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63833738; called by muse, mutect2, varscan2
- FREM2 | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs267603820, COSV54839837; called by muse, mutect2, varscan2
- FRMD4A | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100661408; called by muse, mutect2
- FSTL5 | c.2340G>C p.K780N | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV60198790; called by muse, mutect2, varscan2
- GATM | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV67540579; called by muse, mutect2, varscan2
- GBP2 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as COSV65068398, COSV65069526; called by muse, mutect2, varscan2
- GBP2 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 52/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65069533; called by muse, mutect2, varscan2
- GOLPH3 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as COSV54061033; called by muse, varscan2
- H1-7 | c.629C>A p.A210E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV58601717; called by muse, mutect2, varscan2
- H2AC21 | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV58612152, COSV58613174; called by muse, mutect2, varscan2
- H2BC9 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 10/251 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV55099027, COSV55099687, COSV99769055; called by muse, mutect2
- HLA-DRA | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV66622694; called by muse, mutect2, varscan2
- IRF6 | c.717G>C p.Q239H | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.671); catalogued as COSV65419446; called by muse, mutect2, varscan2
- ITGB1BP1 | c.70A>T p.K24* | Nonsense Mutation (SNP) | VAF 88/506 reads (17%) | catalogued as COSV53006252; called by muse, mutect2, varscan2
- KCNK17 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64685758; called by muse, varscan2
- KLHL28 | c.1547G>C p.R516T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61888295; called by muse, mutect2, varscan2
- L3MBTL4 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV53124547, COSV99527357; called by muse, mutect2, varscan2
- LAMB1 | c.2617G>T p.A873S | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.669); catalogued as COSV55965296, COSV55968086, COSV99739799; called by muse, mutect2, varscan2
- LGALS1 | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV53222209; called by muse, mutect2, varscan2
- LOXL3 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as rs916033845, COSV51208194; called by muse, mutect2, varscan2
- MATR3 | c.2330A>G p.D777G | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.108); catalogued as COSV63077545; called by muse, mutect2, varscan2
- MKRN1 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55436962; called by muse, mutect2, varscan2
- MVD | c.554A>G p.Q185R | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV56330487, COSV56331996; called by muse, mutect2, varscan2
- MYCBP2 | c.10868C>T p.S3623L (on ENST00000357337; = p.S3661L on NM_015057.5) | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV62021649; called by muse, mutect2, varscan2
- NCOA1 | c.3392G>C p.R1131T | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV56045235; called by muse, mutect2, varscan2
- NELL1 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV54271111; called by muse, mutect2, varscan2
- NEXMIF | c.3706A>G p.K1236E | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV50035857; called by muse, mutect2, varscan2
- NFRKB | c.282T>G p.S94R (on ENST00000446488 / NM_001143835.2; = p.S107R on NM_006165.3) | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV58758364; called by muse, mutect2, varscan2
- NME4 | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs778308477, COSV54791571; called by muse, mutect2, varscan2
- NPHP4 | c.1591C>G p.Q531E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65395207; called by muse, varscan2
- OBSCN | c.7829G>A p.R2610Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.736); catalogued as rs766008918, COSV52768570; called by muse, mutect2
- OR5AR1 | c.399C>A p.S133R | Missense Mutation (SNP) | VAF 68/470 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57254032; called by muse, mutect2, varscan2
- PCDHB13 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.057); catalogued as COSV53395546, COSV53397242; called by muse, mutect2, varscan2
- PDE10A | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.304); catalogued as COSV63091518; called by muse, mutect2, varscan2
- PDZD4 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51247229; called by muse, mutect2, varscan2
- PHLDB2 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 20/130 reads (15%) | catalogued as COSV67311920; called by muse, mutect2, varscan2
- PHYH | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as rs751660253, COSV53816174; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITHD1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55755090; called by muse, mutect2, varscan2
- PLA2G5 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.831); catalogued as rs1031628964, COSV64282807, COSV64283108; called by muse, mutect2, varscan2
- PLXNA4 | c.4191G>C p.K1397N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV58130913; called by muse, mutect2, varscan2
- PNMA5 | c.824A>T p.H275L | Missense Mutation (SNP) | VAF 119/333 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV62625698; called by muse, mutect2, varscan2
- PPP1R13L | c.1804C>G p.P602A | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV62908636; called by muse, mutect2, varscan2
- PPP2R1A | c.1217C>G p.P406R | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV59045083; called by muse, mutect2, varscan2
- PPP3CA | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV59924353; called by muse, mutect2, varscan2
- PRX | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV52530369; called by muse, mutect2, varscan2
- PRX | c.1584G>T p.M528I | Missense Mutation (SNP) | VAF 48/288 reads (17%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.838); catalogued as COSV52530379, COSV52534380; called by muse, varscan2
- PTCD3 | c.881T>G p.F294C | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54480549; called by muse, mutect2, varscan2
- PTPRD | c.2969A>T p.Y990F | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV100642515, COSV61952067; called by muse, mutect2, varscan2
- RBM38 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as COSV61134287; called by muse, mutect2
- RNF168 | c.1423C>G p.H475D | Missense Mutation (SNP) | VAF 82/734 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100534949, COSV58838058; called by muse, mutect2, varscan2
- RNF19A | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV61993399; called by muse, mutect2, varscan2
- RYR3 | c.7849G>A p.V2617I (on ENST00000389232; = p.V2618I on NM_001036.6) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs369629619; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAMD9 | c.4392C>G p.F1464L | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1460994810, COSV66075827; called by muse, mutect2, varscan2
- SESN1 | c.350G>T p.R117L (on ENST00000356644 / NM_001199933.1; = p.R176L on NM_014454.3) | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV57420407, COSV57420895; called by muse, mutect2, varscan2
- SLC12A6 | c.520G>A p.E174K (on ENST00000354181 / NM_001365088.1; = p.E123K on NM_005135.2) | Missense Mutation (SNP) | VAF 70/487 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV51626696; called by muse, mutect2, varscan2
- SMG8 | c.1724A>G p.H575R | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.902); catalogued as COSV56285638; called by muse, mutect2, varscan2
- SPATA4 | c.175C>A p.L59I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV54590214; called by muse, mutect2, varscan2
- SPINK4 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV65688056; called by muse, mutect2, varscan2
- STAR | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as rs748942681, COSV52417633; called by muse, mutect2, varscan2
- STAT5B | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV99510753; called by muse, mutect2, varscan2
- TARS2 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64695620; called by muse, mutect2, varscan2
- TASOR2 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 28/705 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV60167771; called by muse, mutect2
- TEX35 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as rs761902287, COSV51104895, COSV51105389; called by muse, mutect2
- TLE2 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 21/130 reads (16%) | catalogued as COSV53580380; called by muse, mutect2, varscan2
- TP53 | c.224del p.P75Lfs*48 | Frame Shift Del (DEL) | VAF 22/119 reads (18%) | catalogued as COSV53349944; called by pindel, varscan2*
- TPH1 | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV51458406; called by muse, mutect2, varscan2
- TTN | c.45374G>C p.R15125P (on ENST00000591111; = p.R7701P on NM_003319.4) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | PolyPhen possibly damaging (0.619); catalogued as COSV59982230, COSV60104301; called by muse, mutect2, varscan2
- TTN | c.18107G>T p.S6036I (on ENST00000591111; = p.S5109I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/59 reads (22%) | PolyPhen benign (0.02); catalogued as COSV60104329; called by muse, mutect2, varscan2
- WAC | c.1375C>G p.Q459E | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61567752, COSV61570303; called by muse, mutect2
- XKR5 | c.65A>T p.Y22F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.204); catalogued as rs757798320, COSV68398347; called by muse, mutect2
- ZNF408 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.258); catalogued as COSV61238337; called by muse, mutect2, varscan2
- SMARCC1 | c.2105dup p.L702Ffs*34 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | called by mutect2, varscan2
- TRAV26-1 | c.309C>G p.Y103* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- VN1R5 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZIC4 | c.689-13_691del p.X230_splice | Splice Site (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel
- ADGRA2 | c.396G>A p.G132= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV59444051; called by muse, mutect2
- AP4E1 | c.1413G>C p.L471= | Silent (SNP) | VAF 8/239 reads (3%) | catalogued as COSV55917419; called by muse, mutect2
- BBC3 | c.597C>T p.P199= (on ENST00000449228 / NM_001127240.3; = p.P165L on NM_014417.5) | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as rs773442047, COSV56262207; called by muse, mutect2, varscan2
- CASZ1 | c.4635C>T p.A1545= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs752586999, COSV65458254; called by muse, mutect2, varscan2
- CSMD1 | c.10674G>A p.L3558= (on ENST00000520002; = p.L3557= on NM_033225.6) | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV59331874; called by mutect2, varscan2
- CSMD1 | c.8775G>C p.G2925= (on ENST00000520002; = p.G2924= on NM_033225.6) | Silent (SNP) | VAF 53/383 reads (14%) | catalogued as rs765458735, COSV59331898; called by muse, mutect2, varscan2
- CSMD2 | c.6309C>A p.V2103= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV53917910; called by muse, mutect2, varscan2
- FANCM | c.3855T>C p.H1285= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as COSV57501911; called by muse, mutect2, varscan2
- FAT3 | c.7422G>A p.G2474= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as rs762824037, COSV53119162; called by muse, mutect2, varscan2
- GP1BA | c.936C>T p.V312= | Silent (SNP) | VAF 24/160 reads (15%) | catalogued as COSV56699656; called by muse, mutect2, varscan2
- H2BC12 | c.159C>T p.T53= | Silent (SNP) | VAF 55/400 reads (14%) | catalogued as rs1487300392, COSV63617095; called by muse, mutect2, varscan2
- HOMER2 | c.99C>T p.T33= | Silent (SNP) | VAF 52/315 reads (17%) | catalogued as rs758783805, COSV58486439; called by muse, mutect2, varscan2
- KDM3A | c.1122G>A p.Q374= | Silent (SNP) | VAF 59/353 reads (17%) | catalogued as COSV57219340, COSV57221698; called by muse, mutect2, varscan2
- KLHDC2 | c.880C>T p.L294= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as COSV53587434; called by muse, mutect2, varscan2
- LAMB1 | c.1479C>T p.C493= | Silent (SNP) | VAF 30/157 reads (19%) | catalogued as COSV55965305; called by muse, mutect2, varscan2
- LRRC71 | c.687C>T p.N229= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1471375045, COSV61656305; called by muse, mutect2, varscan2
- MAGEB6B | c.969A>G p.S323= | Silent (SNP) | VAF 76/410 reads (19%) | called by muse, varscan2
- MATK | c.540C>T p.I180= (on ENST00000310132 / NM_139355.3; = p.I181= on NM_002378.4) | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs1340450382, COSV59554996; called by muse, mutect2, varscan2
- MDC1 | c.5283G>A p.V1761= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV64524922; called by muse, mutect2
- MPND | c.933C>G p.L311= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV53657713; called by muse, mutect2, varscan2
- MYH15 | c.2844G>A p.L948= | Silent (SNP) | VAF 34/237 reads (14%) | catalogued as rs1421452818, COSV56311383; called by muse, mutect2, varscan2
- NEB | c.14373C>T p.I4791= | Silent (SNP) | VAF 46/296 reads (16%) | catalogued as rs113068669, COSV50845681; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUP93 | c.2376G>A p.L792= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV57431265; called by muse, mutect2, varscan2
- OBI1 | c.381T>C p.I127= | Silent (SNP) | VAF 62/258 reads (24%) | catalogued as COSV56145867; called by muse, mutect2, varscan2
- OPCML | c.640C>A p.R214= | Silent (SNP) | VAF 24/229 reads (10%) | catalogued as rs750914544, COSV59405950, COSV59426981; called by muse, mutect2, varscan2
- OR2K2 | c.945C>T p.P315= (on ENST00000374428; = p.P286= on NM_205859.2) | Silent (SNP) | VAF 35/175 reads (20%) | catalogued as COSV57017164; called by muse, mutect2, varscan2
- PAIP2 | c.366G>T p.V122= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV54525668; called by muse, mutect2, varscan2
- PAX3 | c.79C>T p.L27= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV51339831; called by muse, mutect2
- PLCZ1 | c.1467C>T p.I489= | Silent (SNP) | VAF 45/280 reads (16%) | catalogued as rs751542588, COSV56853362; called by muse, mutect2, varscan2
- PRAMEF18 | c.252G>C p.G84= | Silent (SNP) | VAF 46/540 reads (9%) | called by muse, mutect2
- PRR16 | c.342C>G p.L114= (on ENST00000407149 / NM_001300783.2; = p.L91= on NM_016644.2) | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as COSV65400299; called by muse, mutect2, varscan2
- QTRT1 | c.285C>T p.F95= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as COSV51551589, COSV51553352; called by muse, mutect2, varscan2
- RASA4 | c.417G>A p.V139= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- RGR | c.678C>A p.L226= | Silent (SNP) | VAF 35/128 reads (27%) | catalogued as COSV63894165; called by muse, mutect2, varscan2
- SERPINA11 | c.399C>G p.L133= | Silent (SNP) | VAF 60/368 reads (16%) | catalogued as COSV58242118; called by muse, mutect2, varscan2
- SIGLECL1 | c.492A>G p.Q164= | Silent (SNP) | VAF 44/259 reads (17%) | catalogued as COSV57063127; called by muse, mutect2, varscan2
- SPEN | c.5607G>A p.K1869= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV101005058, COSV101005088; called by muse, mutect2
- THBS3 | c.1230G>A p.Q410= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV64249579; called by muse, mutect2, varscan2
- TMEM145 | c.351C>T p.S117= | Silent (SNP) | VAF 42/223 reads (19%) | catalogued as rs772779002, COSV56625573; called by muse, mutect2, varscan2
- ZDHHC5 | c.1041G>A p.P347= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs758935084, COSV54707042; called by muse, mutect2, varscan2
- ZNF184 | c.1323T>A p.T441= | Silent (SNP) | VAF 39/239 reads (16%) | catalogued as COSV53004443; called by muse, mutect2, varscan2
- AATK | c.756-321_756-320delinsA | Intron (DEL) | VAF 10/60 reads (17%) | called by pindel, varscan2*
- AL162726.3 | n.255+83095A>T | Intron (SNP) | VAF 73/376 reads (19%) | called by muse, mutect2, varscan2
- CR1 | c.487+12163T>C | Intron (SNP) | VAF 43/248 reads (17%) | catalogued as COSV100887435; called by muse, mutect2, varscan2
- FAM86C1P | n.172T>C | RNA (SNP) | VAF 17/152 reads (11%) | catalogued as rs1376778066, COSV60639774; called by muse, mutect2, varscan2
- MIR9-1HG | n.472T>C | RNA (SNP) | VAF 5/30 reads (17%) | catalogued as COSV59484014; called by muse, mutect2
- PNKD | c.236+1082G>T | Intron (SNP) | VAF 78/346 reads (23%) | catalogued as COSV99297833; called by muse, mutect2, varscan2
